Somatic mutation profile of tumor specimen 0DSA0B from CCDI case PBCHVP, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Ependymoma, NOS; Tissue or organ of origin: Overlapping lesion of brain; Age at diagnosis: 2.2 years (812 days).
Specimen 0DSA0B: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) afd3f8f3-6c38-4b36-bb88-a344efe4f011.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DSA0U (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/248ece11-489d-4da9-bf16-d434dd00dd3c

The open-access MAF lists 5 somatic variants for this specimen: 5 protein-altering or splice-affecting.
By variant classification: Missense Mutation 4, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- LACTB | c.886G>A p.E296K | Missense Mutation (SNP) | VAF 36/976 reads (4%) | SIFT tolerated (0.48); PolyPhen benign (0.042); catalogued as COSV99978977; called by muse, mutect2
- PPP1R10 | c.2212C>T p.R738* | Nonsense Mutation (SNP) | VAF 189/661 reads (29%) | catalogued as COSV64739216; called by muse, mutect2, varscan2
- PRPH2 | c.82G>A p.V28M | Missense Mutation (SNP) | VAF 24/724 reads (3%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.99); catalogued as rs1476970688; called by muse, mutect2
- TLR10 | c.830G>A p.R277Q | Missense Mutation (SNP) | VAF 359/1309 reads (27%) | SIFT tolerated (0.37); PolyPhen benign (0.001); catalogued as rs372475414; called by muse, mutect2, varscan2
- CLCNKA | c.1613G>T p.R538L | Missense Mutation (SNP) | VAF 205/767 reads (27%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.458); called by muse, mutect2, varscan2
